Somatic mutation profile of tumor specimen MP2PRT-PAVSAX-TMP1-A (aliquot MP2PRT-PAVSAX-TMP1-A-1-0-D-A81Q-36) from MP2PRT case MP2PRT-PAVSAX, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.8 years (1,762 days).
Specimen MP2PRT-PAVSAX-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 12c65074-8ba7-46e6-96f0-1507431fd97f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVSAX-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVSAX-NB1-A-1-0-D-A81Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c8c09ead-ef21-4e70-95dc-e8fb70bf2cd5

The open-access MAF lists 13 somatic variants for this specimen: 12 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 10, Frame Shift Ins 1, Nonsense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 105/289 reads (36%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.525); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- MAGED2 | c.770G>A p.R257H | Missense Mutation (SNP) | VAF 94/1188 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs368156326, COSV104374277; called by muse, mutect2
- NT5C1A | c.679G>A p.A227T | Missense Mutation (SNP) | VAF 26/567 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.405); catalogued as COSV52494151; called by muse, mutect2
- REM1 | c.737G>A p.R246H | Missense Mutation (SNP) | VAF 314/775 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV52429430; called by muse, mutect2, varscan2
- SLC25A15 | c.226G>A p.A76T | Missense Mutation (SNP) | VAF 42/461 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.135); catalogued as rs753073964; called by muse, mutect2
- GOLGA6L2 | c.755A>G p.K252R | Missense Mutation (SNP) | VAF 22/157 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- IGKV1D-8 | c.347_351dup p.*118Sfs*? | Frame Shift Ins (INS) | VAF 37/112 reads (33%) | called by mutect2, pindel, varscan2
- KCNK18 | c.103C>G p.L35V | Missense Mutation (SNP) | VAF 36/761 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.162); called by muse, mutect2
- NALCN | c.350G>T p.C117F | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT tolerated (0.48); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NR2F6 | c.142G>T p.E48* | Nonsense Mutation (SNP) | VAF 26/954 reads (3%) | called by muse, mutect2
- SPANXN3 | c.213A>T p.E71D | Missense Mutation (SNP) | VAF 61/372 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- WNK3 | c.255G>C p.M85I | Missense Mutation (SNP) | VAF 13/376 reads (3%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2
- HELZ2 | c.3216C>T p.D1072= (on ENST00000467148 / NM_001037335.2; = p.D503= on NM_033405.3) | Silent (SNP) | VAF 199/554 reads (36%) | catalogued as rs748560229; called by muse, mutect2, varscan2
